Somatic mutation profile of tumor specimen 0DQZ4G from CCDI case PBCFRZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 11.8 years (4,303 days).
Specimen 0DQZ4G: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caf1f0c7-c745-42f8-a433-d4945fd1a9fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b5f0471-c787-4890-a320-29da1d16a6b6

The open-access MAF lists 48 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Intron 2, Nonsense Mutation 2, 3'UTR 2, Translation Start Site 1, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC27 | c.1679C>G p.T560R | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as COSV50658360; called by muse, mutect2, varscan2
- HCN1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57517608; called by muse, mutect2, varscan2
- LY6D | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781022238, COSV56660994; called by muse, mutect2, varscan2
- MMP27 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs978478682; called by muse, mutect2, varscan2
- NUAK2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.886); catalogued as rs142942069; called by muse, mutect2, varscan2
- SLC22A12 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 147/469 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as rs771103495; called by muse, mutect2, varscan2
- UGT8 | c.1045C>A p.H349N | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); catalogued as rs770333571; called by muse, mutect2, varscan2
- VDR | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs771926584; called by muse, mutect2, varscan2
- ADAMTS8 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- AGAP2 | c.2353C>A p.L785M (on ENST00000547588 / NM_001122772.2; = p.L449M on NM_014770.4) | Missense Mutation (SNP) | VAF 186/2355 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2
- ANK2 | c.10724del p.Y3575Lfs*13 | Frame Shift Del (DEL) | VAF 90/371 reads (24%) | called by mutect2, pindel, varscan2
- ANXA7 | c.580C>T p.L194F (on ENST00000372919 / NM_001320880.2; = p.L172F on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 526/1870 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- APP | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 129/520 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATPAF1 | c.461A>G p.K154R (on ENST00000574428; = p.K177R on NM_022745.4) | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CD200 | c.682G>C p.D228H (on ENST00000473539 / NM_001004196.3; = p.D203H on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CEBPZ | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 22/757 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2
- CEBPZ | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 24/640 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2
- CERS1 | c.126G>C p.W42C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- COPS8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 46/215 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CXCL17 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- DNAH3 | c.9579C>A p.N3193K | Missense Mutation (SNP) | VAF 98/433 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJB12 | c.705A>C p.E235D (on ENST00000338820; = p.E201D on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 988/3768 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA6 | c.540G>C p.W180C | Missense Mutation (SNP) | VAF 83/322 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FSIP2 | c.3868C>T p.Q1290* | Nonsense Mutation (SNP) | VAF 106/549 reads (19%) | called by muse, mutect2, varscan2
- HS3ST4 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MIGA1 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV1 | c.4825G>C p.A1609P | Missense Mutation (SNP) | VAF 260/749 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEK6 | c.810dup p.G271Rfs*19 | Frame Shift Ins (INS) | VAF 57/254 reads (22%) | called by mutect2, pindel, varscan2
- NOS3 | c.3191C>G p.A1064G | Missense Mutation (SNP) | VAF 100/384 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NUBP2 | c.113_115del p.A38_L39delinsV | In Frame Del (DEL) | VAF 61/282 reads (22%) | called by mutect2, pindel, varscan2
- OR4C45 | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 88/421 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEZ6L2 | c.2105T>C p.I702T (on ENST00000308713 / NM_001114099.3; = p.I632T on NM_012410.4) | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- SYCP2L | c.1955-1G>C p.X652_splice | Splice Site (SNP) | VAF 70/496 reads (14%) | called by muse, mutect2, varscan2
- TEP1 | c.6522C>G p.D2174E | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- XRCC5 | c.1966A>C p.N656H | Missense Mutation (SNP) | VAF 88/337 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZGRF1 | c.2970C>A p.F990L | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.938); called by muse, varscan2
- ABRA | c.369C>T p.D123= | Silent (SNP) | VAF 233/513 reads (45%) | catalogued as rs374775448; called by muse, mutect2, varscan2
- ALX3 | c.84G>A p.P28= | Silent (SNP) | VAF 70/236 reads (30%) | catalogued as rs1011770350; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD26 | c.3492G>A p.V1164= | Silent (SNP) | VAF 147/628 reads (23%) | called by muse, mutect2, varscan2
- FSD1L | c.1590A>G p.Q530= | Silent (SNP) | VAF 90/346 reads (26%) | catalogued as rs757917424; called by muse, mutect2, varscan2
- LRIG3 | c.3012C>T p.H1004= | Silent (SNP) | VAF 113/2538 reads (4%) | called by muse, mutect2
- MSS51 | c.897C>T p.V299= | Silent (SNP) | VAF 280/3291 reads (9%) | called by muse, mutect2
- SRL | c.984C>T p.N328= | Silent (SNP) | VAF 117/432 reads (27%) | catalogued as rs375302007; called by muse, mutect2, varscan2
- CRTAM | c.*25T>C | 3'UTR (SNP) | VAF 41/128 reads (32%) | called by muse, mutect2, varscan2
- MOV10 | c.2508+87_2508+89del | Intron (DEL) | VAF 37/116 reads (32%) | called by mutect2, pindel, varscan2
- SKOR1 | chr15:67822109 A>T | 5'Flank (SNP) | VAF 83/270 reads (31%) | called by muse, mutect2, varscan2
- SLC38A10 | c.*63C>T | 3'UTR (SNP) | VAF 42/116 reads (36%) | called by muse, mutect2, varscan2
- SLC6A15 | c.756+134A>C | Intron (SNP) | VAF 34/126 reads (27%) | called by muse, mutect2
